BEATAML1.0 case 2683 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/1ef4588d-fae1-44fd-a73f-1b151bb92ac4

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Acute promyelocytic leukaemia, PML-RAR-alpha: ICD-O-3 morphology code: 9866/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.6 years (18,845 days); Progression or recurrence: no.

Biospecimens (1 sample)
- Sample BA3243R: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
